Somatic mutation profile of tumor specimen TARGET-20-PARHKZ-09A (aliquot TARGET-20-PARHKZ-09A-01D) from TARGET case TARGET-20-PARHKZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (439 days).
Specimen TARGET-20-PARHKZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 265cb174-8693-405a-94cc-4a577014ca1b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARHKZ-10A (Blood Derived Normal), aliquot TARGET-20-PARHKZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfd54e84-d57e-4190-837f-7c416893e8ba

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- PTPN11 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs397507501, CM021125, COSV61008667; ClinVar: pathogenic; called by muse, mutect2, varscan2
